Somatic mutation profile of tumor specimen TCGA-F5-6571-01A (aliquot TCGA-F5-6571-01A-12D-1826-10) from TCGA case TCGA-F5-6571, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 62.1 years (22,666 days).
Specimen TCGA-F5-6571-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 785e32a6-3b18-4087-99c2-9495fc13a87c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-F5-6571-10A (Blood Derived Normal), aliquot TCGA-F5-6571-10A-01D-1826-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ed842a93-836e-4f20-9aae-d867b554f06b

The open-access MAF lists 76 somatic variants for this specimen: 61 protein-altering or splice-affecting, 14 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 14, Nonsense Mutation 8, Frame Shift Del 3, In Frame Del 2, Splice Site 1, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.2626C>T p.R876* | Nonsense Mutation (SNP) | VAF 7/41 reads (17%) | hotspot (GDC flag); catalogued as rs121913333, CM942020, COSV57320538; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CLCN5 | c.1039C>T p.R347* | Nonsense Mutation (SNP) | VAF 11/70 reads (16%) | catalogued as rs797044810, CM983859, COSV56582168; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GDF5 | c.466C>T p.R156* | Nonsense Mutation (SNP) | VAF 48/108 reads (44%) | catalogued as rs1194065564, COSV65499765; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 44/125 reads (35%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- TP53 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 36/64 reads (56%) | hotspot (GDC flag); catalogued as rs397516435, CM941329, COSV52663748, COSV53125285, COSV53128268; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AMY2A | c.406C>A p.P136T | Missense Mutation (SNP) | VAF 78/344 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV70214801; called by muse, mutect2
- ANGPT4 | c.1475G>A p.R492H | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.288); catalogued as rs775939876, COSV67920810; called by muse, mutect2, varscan2
- ANKRD30A | c.1291G>A p.V431M (on ENST00000611781; = p.V375M on NM_052997.2) | Missense Mutation (SNP) | VAF 58/126 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.189); catalogued as rs373496322, COSV64609083; called by muse, mutect2, varscan2
- ANKRD42 | c.650T>A p.L217* | Nonsense Mutation (SNP) | VAF 29/81 reads (36%) | catalogued as COSV52614616; called by muse, mutect2, varscan2
- ASXL1 | c.961C>T p.R321W | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60104086; called by muse, mutect2, varscan2
- BSN | c.3397G>A p.D1133N | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV56513825; called by muse, mutect2, varscan2
- C15orf39 | c.1358G>A p.R453Q | Missense Mutation (SNP) | VAF 32/47 reads (68%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs750032775, COSV62295871; called by muse, mutect2, varscan2
- C16orf92 | c.221C>G p.S74* | Nonsense Mutation (SNP) | VAF 11/31 reads (35%) | catalogued as COSV54226340; called by muse, mutect2, varscan2
- CAPRIN2 | c.1265C>A p.S422Y | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.742); catalogued as COSV99195409; called by muse, mutect2
- CCDC40 | c.506C>T p.S169L | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs369066468; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDK12 | c.2335C>T p.R779C | Missense Mutation (SNP) | VAF 43/94 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1217963220, COSV70999525; called by muse, mutect2, varscan2
- CDKL5 | c.952G>A p.V318M | Missense Mutation (SNP) | VAF 16/218 reads (7%) | SIFT tolerated, low confidence (0.25); PolyPhen possibly damaging (0.556); catalogued as COSV66110402; called by muse, mutect2
- COL22A1 | c.3186G>A p.P1062= | Splice Region (SNP) | VAF 16/46 reads (35%) | catalogued as rs371517268; called by muse, mutect2, varscan2
- DNAH3 | c.8972G>A p.R2991H | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.04); catalogued as rs368894340; called by muse, mutect2, varscan2
- DPP10 | c.1367C>G p.S456C | Missense Mutation (SNP) | VAF 7/162 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs1340074558, COSV100058401; called by muse, mutect2
- EDNRB | c.1315C>G p.L439V (on ENST00000377211 / NM_001201397.1; = p.L349V on NM_000115.5) | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as COSV104398502, COSV57519484; called by muse, mutect2, varscan2
- ERCC4 | c.1621G>A p.D541N | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.228); catalogued as COSV61310928, COSV61311204; called by muse, mutect2, varscan2
- FAAP100 | c.2074G>T p.G692* | Nonsense Mutation (SNP) | VAF 12/30 reads (40%) | catalogued as COSV59884038; called by muse, mutect2, varscan2
- FAM13C | c.776C>T p.S259F | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV53244203; called by muse, mutect2
- FGGY | c.1597G>A p.V533I | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.545); catalogued as COSV58027422; called by muse, mutect2, varscan2
- FRMPD3 | c.4702G>T p.V1568L | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.938); catalogued as COSV99345612; called by muse, mutect2, varscan2
- HS3ST4 | c.452C>T p.T151M | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.747); catalogued as COSV58804186; called by muse, mutect2, varscan2
- ICAM5 | c.2255C>T p.A752V | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.114); catalogued as COSV55746320; called by muse, mutect2
- IMPG1 | c.200G>A p.R67Q | Missense Mutation (SNP) | VAF 34/302 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV64054719; called by muse, mutect2, varscan2
- INTU | c.593G>T p.R198I | Missense Mutation (SNP) | VAF 47/76 reads (62%) | SIFT deleterious (0.02); PolyPhen benign (0.205); catalogued as COSV56538486, COSV56541984; called by muse, mutect2, varscan2
- KIAA1109 | c.1272G>A p.M424I | Missense Mutation (SNP) | VAF 33/64 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV52664265; called by muse, mutect2, varscan2
- MAPK8IP1 | c.917G>A p.R306Q | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); catalogued as rs771448062, COSV53796895, COSV53798019; called by muse, mutect2, varscan2
- MXRA5 | c.4525A>G p.T1509A | Missense Mutation (SNP) | VAF 59/107 reads (55%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV54226291; called by muse, mutect2, varscan2
- NHS | c.4867G>T p.D1623Y | Missense Mutation (SNP) | VAF 22/37 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66272098; called by muse, mutect2, varscan2
- NKAP | c.988C>T p.R330C | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.861); catalogued as COSV65055972; called by muse, mutect2, varscan2
- OR10C1 | c.328G>A p.A110T (on ENST00000622521; = p.A108T on NM_013941.3) | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated (0.51); PolyPhen benign (0.019); catalogued as rs1222025759, COSV65822346; called by muse, mutect2, varscan2
- OXER1 | c.808T>C p.F270L | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1265408512, COSV54309927; called by muse, mutect2, varscan2
- PCDH17 | c.1834G>A p.A612T | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64975650; called by muse, mutect2
- PCDHB13 | c.770C>T p.P257L | Missense Mutation (SNP) | VAF 38/132 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.598); catalogued as COSV53393733; called by muse, mutect2, varscan2
- PCLO | c.5729C>T p.A1910V | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs375287995; called by muse, mutect2
- PRKCB | c.1007G>A p.R336Q | Missense Mutation (SNP) | VAF 52/130 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as rs1163412779, COSV57768797, COSV57799135; called by muse, mutect2, varscan2
- PRKN | c.885C>A p.N295K | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.221); catalogued as COSV58205767; called by muse, mutect2, varscan2
- RDX | c.836G>A p.R279Q | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.904); catalogued as rs150863373; called by muse, mutect2, varscan2
- RIMBP3 | c.3085C>T p.R1029* | Nonsense Mutation (SNP) | VAF 38/374 reads (10%) | catalogued as rs766626808; called by muse, mutect2, varscan2
- RNF130 | c.818A>T p.Q273L | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV99992473; called by muse, mutect2, varscan2
- SCN11A | c.617+1G>A p.X206_splice | Splice Site (SNP) | VAF 49/147 reads (33%) | catalogued as rs754708932, COSV56566681; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC6A5 | c.454G>A p.V152M | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.28); catalogued as COSV54224272; called by muse, mutect2, varscan2
- SNAI1 | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 25/37 reads (68%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54863674; called by muse, mutect2, varscan2
- SOX11 | c.1192G>T p.D398Y | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV58983641; called by muse, mutect2, varscan2
- SPANXN2 | c.47C>A p.P16H | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100979774; called by muse, mutect2, varscan2
- SPATA31E1 | c.527C>T p.P176L | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.138); catalogued as rs577973609, COSV100350844, COSV57789888; called by muse, mutect2, varscan2
- TAB2 | c.611T>A p.V204E | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.28); PolyPhen benign (0.014); catalogued as COSV53851245; called by muse, mutect2, varscan2
- TAF7L | c.994_996del p.N332del | In Frame Del (DEL) | VAF 14/114 reads (12%) | catalogued as rs770020614, COSV61256425; called by mutect2, pindel, varscan2
- TAS2R50 | c.752G>A p.S251N | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT tolerated (0.73); PolyPhen benign (0.006); catalogued as rs772131984, COSV67853158; called by muse, mutect2
- ZNF425 | c.1610G>A p.R537Q | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.013); catalogued as rs771074499, COSV65200722; called by muse, mutect2, varscan2
- APC | c.4483del p.S1495Vfs*12 | Frame Shift Del (DEL) | VAF 19/68 reads (28%) | called by mutect2, pindel, varscan2
- CYP4Z1 | c.1309del p.I437Yfs*13 | Frame Shift Del (DEL) | VAF 114/332 reads (34%) | called by mutect2, varscan2
- FKBP8 | c.104_115del p.G35_E38del | In Frame Del (DEL) | VAF 27/54 reads (50%) | called by mutect2, pindel, varscan2
- FRMPD2 | c.1676C>T p.P559L | Missense Mutation (SNP) | VAF 5/101 reads (5%) | SIFT tolerated (0.7); PolyPhen benign (0.006); called by muse, mutect2
- IGLV2-33 | c.296T>C p.L99P | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SLCO6A1 | c.1576del p.S526Lfs*29 | Frame Shift Del (DEL) | VAF 45/107 reads (42%) | called by mutect2, pindel, varscan2
- DNAJB12 | c.468G>A p.S156= (on ENST00000338820; = p.S122= on NM_017626.6 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 41/107 reads (38%) | catalogued as rs752474265, COSV58759799; called by muse, mutect2, varscan2
- DNMT1 | c.3672G>C p.P1224= | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as COSV61576967; called by muse, mutect2, varscan2
- EDN1 | c.366T>C p.F122= | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as COSV101040260; called by muse, mutect2, varscan2
- FAM71A | c.1452C>T p.S484= | Silent (SNP) | VAF 15/40 reads (38%) | catalogued as rs764185348, COSV54234810; called by muse, mutect2, varscan2
- KCNB1 | c.270C>T p.G90= | Silent (SNP) | VAF 88/124 reads (71%) | catalogued as rs762279881, COSV65566177, COSV65566453; called by muse, mutect2, varscan2
- MED26 | c.1356G>A p.E452= | Silent (SNP) | VAF 31/66 reads (47%) | catalogued as COSV54658992; called by muse, mutect2, varscan2
- PDCD11 | c.5193C>T p.Y1731= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as rs777443590, COSV53294509; called by muse, mutect2, varscan2
- PPP1R12C | c.2004C>T p.L668= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as COSV52380263; called by muse, mutect2, varscan2
- PRSS57 | c.306G>A p.V102= | Silent (SNP) | VAF 18/62 reads (29%) | catalogued as COSV61385525; called by muse, mutect2, varscan2
- SPAM1 | c.1521G>A p.A507= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as rs757443409, COSV56143019; called by mutect2, varscan2
- TFIP11 | c.1350G>A p.E450= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as COSV53225641; called by muse, mutect2, varscan2
- TGFBI | c.747C>T p.I249= | Silent (SNP) | VAF 33/60 reads (55%) | catalogued as rs772472646, COSV59350162; called by muse, mutect2, varscan2
- WASF3 | c.1488C>T p.D496= | Silent (SNP) | VAF 111/137 reads (81%) | catalogued as rs1042958932, COSV58963132; called by muse, mutect2, varscan2
- ZNF804A | c.3573C>A p.L1191= | Silent (SNP) | VAF 21/150 reads (14%) | catalogued as COSV100168238, COSV56437929; called by muse, mutect2, varscan2
- PKD1L2 | n.1302G>A | RNA (SNP) | VAF 12/35 reads (34%) | catalogued as rs865895361; called by muse, mutect2, varscan2
